Somatic mutation profile of tumor specimen 0DG5AH from CCDI case PBBSZS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 4.2 years (1,522 days).
Specimen 0DG5AH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b83bac4a-4cca-4f15-acc6-1ae358ac7e1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG5AE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bb1627c-fc22-40ea-801e-51cd785aaeee

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Intron 6, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>A p.R465S (on ENST00000281708 / NM_001349798.2; = p.R385S on NM_018315.5) | Missense Mutation (SNP) | VAF 260/723 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55891008, COSV55897912, COSV99654845; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 430/947 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA7 | c.4082C>A p.A1361D | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs756927470; called by muse, varscan2
- ADAM15 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 79/362 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); catalogued as COSV55057579; called by muse, mutect2, varscan2
- AGXT | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs372021565; called by muse, mutect2, varscan2
- CSMD2 | c.3902C>A p.T1301N | Missense Mutation (SNP) | VAF 22/540 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV53875013; called by muse, mutect2
- DLG3 | c.1489C>T p.R497* (on ENST00000374360 / NM_021120.4; = p.R160* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 172/273 reads (63%) | catalogued as rs1228853521, COSV99529893; called by muse, mutect2, varscan2
- FAM217B | c.84C>G p.H28Q | Missense Mutation (SNP) | VAF 258/1108 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV62565286; called by mutect2, varscan2
- GPX6 | c.521T>C p.M174T | Missense Mutation (SNP) | VAF 156/506 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV62657488; called by muse, mutect2, varscan2
- IRS2 | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV65477460; called by muse, mutect2, varscan2
- MYBL1 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 143/644 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.226); catalogued as rs760647023; called by muse, mutect2, varscan2
- ANK3 | c.985T>C p.S329P | Missense Mutation (SNP) | VAF 118/480 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CHSY1 | c.977_983dup p.H329Afs*25 | Frame Shift Ins (INS) | VAF 134/465 reads (29%) | called by mutect2, varscan2
- CLIP3 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 106/528 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CPNE8 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- CYTH2 | c.256A>G p.N86D | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- HPX | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 103/391 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- MMRN2 | c.2402C>G p.P801R | Missense Mutation (SNP) | VAF 20/656 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2
- PGLYRP2 | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, varscan2
- RHOT2 | c.1170G>C p.E390D | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SP100 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 206/1165 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SPATA31A1 | c.3243C>A p.S1081R | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.067); called by mutect2, varscan2
- TEAD2 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by mutect2, varscan2
- TRIP12 | c.4439C>A p.A1480D | Missense Mutation (SNP) | VAF 141/1053 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- VAV1 | c.131G>T p.C44F | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX3 | c.3644A>G p.E1215G | Missense Mutation (SNP) | VAF 187/666 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ALAS2 | c.598C>T p.L200= | Silent (SNP) | VAF 202/308 reads (66%) | called by muse, mutect2, varscan2
- ARHGEF35 | c.1407T>C p.F469= | Silent (SNP) | VAF 22/911 reads (2%) | called by muse, mutect2
- CCDC93 | c.1449C>G p.R483= | Silent (SNP) | VAF 165/940 reads (18%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.2064C>T p.T688= | Silent (SNP) | VAF 49/194 reads (25%) | catalogued as rs1043830490; called by muse, mutect2, varscan2
- SNX32 | c.1029G>A p.L343= | Silent (SNP) | VAF 108/402 reads (27%) | catalogued as COSV100362608; called by muse, mutect2, varscan2
- VSIG10L | c.2133G>T p.L711= | Silent (SNP) | VAF 15/290 reads (5%) | called by muse, mutect2
- C3orf80 | c.*32G>T | 3'UTR (SNP) | VAF 27/113 reads (24%) | called by muse, mutect2, varscan2
- CES4A | c.1316-55G>T | Intron (SNP) | VAF 43/131 reads (33%) | called by muse, mutect2, varscan2
- CMTM1 | c.81+122G>A | Intron (SNP) | VAF 100/380 reads (26%) | catalogued as rs1306010472, COSV104381962; called by muse, mutect2, varscan2
- DNAH12 | c.6930-24824G>A | Intron (SNP) | VAF 186/895 reads (21%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 9/164 reads (5%) | called by muse, mutect2
- PALM3 | c.46-29del | Intron (DEL) | VAF 10/46 reads (22%) | called by mutect2, varscan2
- TATDN1 | c.138+54T>A | Intron (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
